Somatic mutation profile of tumor specimen 0DMUZ7 from CCDI case PBCASG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 2.0 years (745 days).
Specimen 0DMUZ7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e4e4a02-5648-466a-a936-091c5c1fbbf5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMUXC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/57b6e246-1134-43d0-aeb0-2efba8af4103

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC11 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 216/662 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs750296570, COSV62321425; called by muse, mutect2, varscan2
- MAGEC1 | c.3117G>T p.E1039D | Missense Mutation (SNP) | VAF 18/316 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.874); catalogued as rs910809078, COSV53582781; called by muse, mutect2
- MRPL14 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 186/536 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142865447; called by muse, mutect2, varscan2
- ZFHX2 | c.5582G>A p.R1861H | Missense Mutation (SNP) | VAF 98/259 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs370465817, COSV70219854; called by muse, mutect2, varscan2
- FAM47C | c.1087G>A p.V363I | Missense Mutation (SNP) | VAF 18/491 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.092); called by muse, mutect2
- ADGRE5 | c.2463C>T p.G821= (on ENST00000242786 / NM_078481.4; = p.G728= on NM_001784.5) | Silent (SNP) | VAF 105/352 reads (30%) | catalogued as rs781353076; called by muse, mutect2, varscan2
- OPRK1 | c.963C>A p.T321= | Silent (SNP) | VAF 18/278 reads (6%) | catalogued as COSV55569403, COSV99653862; called by muse, mutect2
